CCDI case PBBMYG — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/a22610e7-2a11-433b-9aa5-8596c6cd9e02

Demographics
Sex at birth: male; Race: asian.

Diagnoses (1)
1. Atypical teratoid/rhabdoid tumor: ICD-O-3 morphology code: 9508/3; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 3.9 years (1,414 days).

Biospecimens (3 samples)
- Sample 0DCUKU: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DCUL0: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DCUL4: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
